Somatic mutation profile of tumor specimen TCGA-CA-5255-01A (aliquot TCGA-CA-5255-01A-11D-1835-10) from TCGA case TCGA-CA-5255, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 45.8 years (16,743 days).
Specimen TCGA-CA-5255-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 516c6d65-d526-4601-b5bc-b4c05f157ddf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CA-5255-10A (Blood Derived Normal), aliquot TCGA-CA-5255-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/340b77e2-3590-4488-baf7-2884acab7d20

The open-access MAF lists 47 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 32, Silent 10, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 66/124 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1607T>G p.L536R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61686021, COSV61689552, COSV61689728, COSV61691591; called by muse, mutect2
- ALDH5A1 | c.870G>A p.K290= | Splice Region (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100708758; called by muse, mutect2, varscan2
- ANK2 | c.9688A>G p.T3230A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs200594514, COSV100000726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP3B2 | c.2668G>A p.G890R (on ENST00000261722; = p.G884R on NM_004644.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.403); catalogued as rs760395320, COSV99916147; called by muse, mutect2, varscan2
- ASB13 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202154158, COSV100731343; called by muse, mutect2, varscan2
- CHSY1 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as COSV99573765; called by muse, mutect2, varscan2
- CMYA5 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV71404008; called by muse, mutect2
- DEFB116 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs1439971535, COSV101269221; called by muse, mutect2, varscan2
- ETV6 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67148720; called by muse, mutect2, varscan2
- GSK3A | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1035974110, COSV55900762; called by muse, mutect2, varscan2
- IDH3A | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99357206; called by muse, mutect2
- KMT2B | c.2921G>A p.R974H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.945); catalogued as rs769004875, COSV99719218; called by muse, mutect2, varscan2
- LDHC | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs760395380, COSV55004394; called by muse, mutect2, varscan2
- LRRTM3 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100791562; called by muse, mutect2, varscan2
- MAP1A | c.5721G>T p.K1907N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100288383; called by muse, varscan2
- MARS1 | c.212del p.L71Cfs*33 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs751080704; called by mutect2, varscan2
- MGAT4B | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1287108102, COSV99482143; called by muse, mutect2, varscan2
- MRPL44 | c.206A>G p.H69R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as rs1177151903, COSV99285176; called by muse, mutect2, varscan2
- MYH10 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV99344674; called by muse, mutect2
- MYH10 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99344679; called by muse, mutect2
- MYNN | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.857); catalogued as rs374143807; called by muse, mutect2, varscan2
- MYO1H | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752481845, COSV60446537; called by mutect2, varscan2
- OR6C75 | c.665C>A p.T222K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV100595300; called by muse, mutect2, varscan2
- PPP2R2C | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs371827360; called by mutect2, varscan2
- PSMC3 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs1471140987, COSV100099410; called by muse, mutect2, varscan2
- REG4 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99858445; called by muse, mutect2, varscan2
- SALL1 | c.2925T>G p.S975R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV99172982; called by muse, mutect2, varscan2
- SEPTIN3 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1231090079, COSV52172545; called by muse, mutect2, varscan2
- TFIP11 | c.2245C>T p.Q749* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99314515; called by muse, mutect2, varscan2
- TFIP11 | c.2244G>A p.M748I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV99314520; called by muse, mutect2, varscan2
- TNNT1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99402787; called by muse, varscan2
- TTC13 | c.692G>C p.R231P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100792896, COSV64170316; called by muse, mutect2, varscan2
- AXIN2 | c.764dup p.R256Efs*13 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- PTGES3 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by mutect2, varscan2
- SOX9 | c.1239_1241del p.H413_S414delinsQ | In Frame Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel*, varscan2
- ACCSL | c.291T>A p.P97= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV66579796; called by muse, mutect2, varscan2
- ADH1B | c.1116C>T p.V372= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV100520692; called by muse, mutect2, varscan2
- IL27 | c.96C>A p.P32= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV63559019; called by mutect2, varscan2
- LRRK2 | c.5790C>A p.P1930= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100109695; called by muse, mutect2, varscan2
- MYO16 | c.354C>T p.N118= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs141043025; called by muse, mutect2, varscan2
- PITRM1 | c.1669C>T p.L557= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99828514; called by muse, mutect2, varscan2
- SLC9A8 | c.90G>A p.T30= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs573582561, COSV100846247; called by mutect2, varscan2
- SLF2 | c.906G>T p.L302= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV99488838; called by muse, mutect2, varscan2
- TRIM58 | c.891C>T p.P297= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs745534672, COSV63572003; called by muse, mutect2, varscan2
- ZNF304 | c.1614A>G p.K538= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99988524; called by muse, mutect2, varscan2
